Surgical pathology report (de-identified scan), TCGA case TCGA-RT-A6Y9, project TCGA-PCPG (Pheochromocytoma and Paraganglioma), tissue source site Cleveland Clinic Foundation, specimen TCGA-RT-A6Y9-01A (Primary Tumor).

[page 1 of 2]
Results

Patient Info

Patient Name

Sex

DOB

Component Results

Surgical Pathology Report:

Specimen #:

Physician:

FINAL DIAGNOSIS

RIGHT ADRENAL GLAND, ADRENALECTOMY - PHEOCHROMOCYTOMA (3.3 CM IN GREATEST DIMENSION).

Electronic Signature

SPECIMEN SUBMITTED

A: RIGHT ADRENAL

CLINICAL DATA

PHEOCHROMOCYTOMA

GROSS DESCRIPTION

A. The specimen consists of an ovoid mass measuring 3.3 cm in greatest dimension and weighing 14.0 grams. The tumor mass appears well encapsulated. The mass cuts with little resistance. Cross sections reveal the sharply circumscribed nature of the lesion. The cut surface is tan-brown, heterogenous. Cystic spaces are not present. A thin rim of residual adrenal tissue is noted at the edge of the specimen. The external aspect of the specimen is inked black. A photograph is. Sections are submitted under the following designations: A1 mass in relation to inked external surface, A2-A4 additional non-marginal representative sections of mass, A5 unremarkable appearing adrenal gland.

Date of Report:

Date of Procedure:

Date of Receipt:

Submitted by:

Location:

Lab and Collection

SURGICAL PATHOLOGY

- Lab and Collection Information

Result History

SURGICAL PATHOLOGY

Order Result History Report.

[page 2 of 2]
Encounter Date:

Result Information

Result Date and Time	Status	Provider Status
	Final result	Reviewed

This result is currently released to

By:

Display Full Result Report

Display Order Report

Source: NCI Genomic Data Commons file 4d925210-458d-4900-9d9e-d71355a99a5c (TCGA-RT-A6Y9.FE213B2F-01DE-4845-9FE0-B1FCE7BAC1EB.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).